Somatic mutation profile of tumor specimen 0DQHB2 from CCDI case PBCFDH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.8 years (1,372 days).
Specimen 0DQHB2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c9a89e83-34e5-46b0-870c-2cf66224e0b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQHAK (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4979415-da2c-4ec8-96e0-a566bd9a5a4c

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Frame Shift Del 1, Nonsense Mutation 1, Silent 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSF1R | c.1754-7G>A | Splice Region (SNP) | VAF 116/233 reads (50%) | catalogued as rs755134660; called by muse, mutect2, varscan2
- EXOC6B | c.762del p.F254Lfs*5 | Frame Shift Del (DEL) | VAF 430/998 reads (43%) | catalogued as COSV99724159; called by mutect2, varscan2
- RYR1 | c.3419G>A p.R1140H | Missense Mutation (SNP) | VAF 51/336 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.782); catalogued as rs748318655, COSV100615705, COSV62107125; called by muse, mutect2, varscan2
- TTN | c.33211G>T p.E11071* (on ENST00000591111; = p.E10144* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 46/996 reads (5%) | catalogued as COSV60279306; called by muse, mutect2
- UBALD2 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 22/378 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.019); called by muse, mutect2
- TTN | c.4170G>A p.P1390= (on ENST00000591111; = p.P1344= on NM_003319.4) | Silent (SNP) | VAF 160/713 reads (22%) | catalogued as rs369005241, COSV59869466; ClinVar: likely benign; called by muse, mutect2, varscan2
- KPTN | c.999+31C>T | Intron (SNP) | VAF 108/228 reads (47%) | catalogued as rs767931198; called by muse, mutect2, varscan2
